CCDI case PBBYTG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/fb9c5572-4ae9-46aa-8fe5-fe3e0712f8b6

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 23.6 years (8,625 days).

Biospecimens (3 samples)
- Sample 0DLRHI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLRHS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLRI3: Tissue type: Tumor; Specimen type: Solid Tissue.
